TCGA case TCGA-CF-A9FL — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/96292f0e-5d09-4c44-8dfc-73ebde6bf137

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 85 years; Vital status: Dead; Days to death: 565 days (1.5 years).

Diagnoses (3)
1. Papillary transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8130/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 85.1 years (31,099 days); Year of diagnosis: 2013; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 565 days (1.5 years).
   Pathology details: Consistent pathology review: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC). Age at diagnosis: 75.0 years (27,403 days); Days to diagnosis: -3,696 days (-10.1 years).
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Papillary transitional cell carcinoma). Age at diagnosis: 86.0 years (31,421 days); Days to diagnosis: 322 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 84 days; Disease response: Tumor Free.
- Day 322 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 322 days.
- Days to follow up: 565 days (1.5 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 45 kg; Height: 165 cm; BMI: 16.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CF-A9FL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 350 mg.
  Slide TCGA-CF-A9FL-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CF-A9FL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CF-A9FL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Endoscopic Biopsy; Lymph nodes examined: No; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: No; Treatment outcome first course: Complete Remission/Response.
- History non muscle invasive blca: Noninvasive bladder history: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 565 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 565 days; disease-free interval: event (new tumor event after initially disease-free), 322 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 322 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CF-A9FL-01A-11D-A38F-01): tumor purity 0.85, ploidy 2, whole-genome doublings 0.
